Gene-level copy-number profile of tumor specimen TCGA-5X-AA5U-01A from TCGA case TCGA-5X-AA5U, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary serous cystadenocarcinoma; Tissue or organ of origin: Ovary; FIGO stage: Stage IIC; Tumor grade: GX; Age at diagnosis: 61.4 years (22,438 days).
Specimen TCGA-5X-AA5U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.e1aceff8-11e2-404b-ba6d-bdad05a7116b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-5X-AA5U-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2897ef60-f262-40df-a6ed-26dc711ada2d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 96; copy number 1: 28; copy number 2: 9,783; copy number 3: 26,267; copy number 4: 12,858; copy number 5: 7,001; copy number 6: 1,977; copy number 7: 311; copy number 8: 575; copy number 9: 343; copy number 10: 286; copy number 11: 109; copy number 12: 42; copy number 14: 23; copy number 17: 114.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-5X-AA5U-01A-11D-A402-01): tumor purity 0.86, ploidy 3.56, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 96 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:137,867,925–138,124,624, 2 genes (within-gene range 0–1): AL772363.1, CACNA1B.
- chr14:18,333,726–20,149,745, 94 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,803 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:7,260,871–9,405,683, 30 genes, copy number 7: AC010904.2, AC010904.1, AC013460.1, RNU6ATAC37P, AC092580.4, AC092580.2, LINC01871, AC092580.3, AC092580.1, AC007463.1, LINC00298, AC007463.2, LINC00299, U91324.1, LINC01814, AC092617.1, AC011747.1, SNRPEP5, ID2-AS1, ID2, KIDINS220, MBOAT2, HMGB1P25, RPL30P3, AC093904.2, AC093904.4, AC093904.3, AC093904.1, ASAP2, EIF1P7.
- chr2:103,109,759–104,077,778, 10 genes, copy number 7 (within-gene range 5–7): AC073987.1, AC010881.1, AC011593.1, CRLF3P1, AC018880.1, CAPZBP1, AC013727.1, AC013727.2, LINC01965, AC013727.3.
- chr2:112,641,832–114,420,302, 59 genes, copy number 7–17: AC079922.2, SLC20A1, NT5DC4, CKAP2L, IL1A, AC079753.2, IL1B, AC079753.1, XIAPP3, IL37, CDK8P2, IL36G, HMGN2P23, POLR2DP1, IL36A, IL36B, IL36RN, IL1F10, RNU6-1180P, IL1RN, PSD4, AC016683.1, PAX8-AS1, PAX8, AC016745.1, IGKV1OR2-108, AC016745.2, CBWD2, FOXD4L1, LINC01961, PGM5P4-AS1, PGM5P4, FAM138B, AL078621.2, MIR1302-3, WASH2P, DDX11L2, AL078621.1, RPL23AP7, RABL2A, SNRPA1P1, ACRP1, AC017074.2, AC017074.1, RNU6-744P, SLC35F5, MIR4782, AC104653.2, AC104653.1, AC110769.2, ACTR3, AC110769.3, LINC01191, AC110769.1, U3, AC010982.2, AC010982.1, SEPHS1P7, RNU2-41P.
- chr2:114,828,432–114,835,588, 2 genes, copy number 8: DPP10-AS3, DPP10-AS2.
- chr9:14,475–43,045,120, 776 genes, copy number 8–12 (broad region; genes not listed).
- chr9:68,935,873–69,274,615, 6 genes, copy number 7 (within-gene range 4–11): RNU6-820P, PRKACG, AL358113.1, FXN, AL162730.1, TJP2.
- chr12:990,509–1,504,424, 5 genes, copy number 9 (within-gene range 2–9): ERC1, HTR1DP1, AC004672.1, AC004672.2, LINC00942.
- chr12:1,970,786–2,697,950, 1 gene, copy number 8 (within-gene range 4–8): CACNA1C.
- chr12:2,332,861–3,366,122, 35 genes, copy number 8 (within-gene range 2–8): AC005293.1, AC005414.1, CACNA1C-AS3, AC007618.1, CACNA1C-AS2, CACNA1C-AS1, ITFG2-AS1, AC092471.2, LINC02371, IQSEC3P1, AC092471.1, RPL23AP14, CBX3P4, FKBP4, ITFG2-AS1, AC005841.1, ITFG2, NRIP2, TEX52, FOXM1, RHNO1, TULP3, AC005911.1, RNU6-1315P, TEAD4, AC125807.2, AC125807.1, TSPAN9, Metazoa_SRP, TSPAN9-IT1, AC005912.2, AC005912.1, AC005865.1, AC005865.2, LINC02827.
- chr12:20,361,732–26,421,462, 97 genes, copy number 17 (broad region; genes not listed).
- chr12:26,335,864–26,373,733, 2 genes, copy number 17: AC055720.2, RNA5SP354.
- chr12:31,671,142–32,107,528, 20 genes, copy number 10 (within-gene range 4–10): AMN1, STMN1P1, AC023157.2, AC023157.1, IFITM3P2, H3-5, RNU6-1069P, AC023050.2, AC023050.3, LINC02422, AC023050.4, AC023050.1, RPL12P32, AC023050.5, RESF1, AC016957.2, AC016957.1, AC048344.2, AC048344.3, AC048344.1.
- chr12:32,109,076–32,109,602, 1 gene, copy number 10: AC048344.4.
- chr18:47,390–23,437,961, 429 genes, copy number 7–9 (within-gene range 3–9) (broad region; genes not listed).
- chr18:62,187,255–63,726,432, 30 genes, copy number 8: RELCH, AC027514.1, AC027514.2, TNFRSF11A, Y_RNA, AC100843.1, RPL17P44, AC100843.2, ACTBP9, ZCCHC2, AC064801.1, AC064801.2, RN7SL705P, PHLPP1, RNU6-142P, BCL2, AC022726.1, AC022726.2, KDSR, AC036176.1, VPS4B, AC036176.2, SERPINB5, AC036176.3, ATP5MC1P6, SERPINB12, SERPINB13, SERPINB4, SERPINB11, SERPINB3.
- chr19:6,887,566–7,864,976, 49 genes, copy number 9: ADGRE1, AC020895.2, AC020895.1, Metazoa_SRP, ADGRE4P, AC025278.1, AC025278.2, AC025278.3, MBD3L2B, MBD3L5, MBD3L4, MBD3L2, MBD3L3, ZNF557, INSR, AC119396.1, AC008878.3, AC119396.2, ARHGEF18, PEX11G, TEX45, AC008878.1, ZNF358, AC008878.4, MCOLN1, AC008878.2, PNPLA6, CAMSAP3, MIR6792, XAB2, PET100, AC008763.2, PCP2, AC008763.1, STXBP2, RPS27AP19, RETN, MCEMP1, AC008763.3, TRAPPC5, FCER2, CLEC4G, AC008763.4, CD209, RPL21P129, CLEC4M, CLEC4GP1, EXOSC3P2, EVI5L.
- chr19:29,665,459–30,060,797, 14 genes, copy number 8 (within-gene range 6–8): PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4.
- chr19:34,837,889–36,246,257, 112 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr19:38,915,266–41,137,308, 125 genes, copy number 8–11 (within-gene range 2–11) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 28. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
